Gene-level copy-number profile of tumor specimen C3L-03968-01 from CPTAC case C3L-03968, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.9 years (22,241 days).
Specimen C3L-03968-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e0a4ff46-e4d3-4ce1-a8f2-fd18319c35a3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03968-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/0a98d077-d49c-440a-aa0c-a6433f6791d0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 19; copy number 2: 1,803; copy number 3: 13,743; copy number 4: 30,001; copy number 5: 7,719; copy number 6: 4,368; copy number 7: 319; copy number 8: 247; copy number 9: 48; copy number 10: 9; copy number 12: 5; copy number 13: 3; copy number 15: 2; copy number 20: 1; copy number 61: 2; copy number 79: 24; copy number 94: 1; copy number 105: 20; copy number 106: 9; copy number 113: 22.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr11:50,409,042–54,725,816, 12 genes: AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 146 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:15,668,684–16,769,567, 24 genes, copy number 79: AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1.
- chr4:51,843,000–52,551,574, 11 genes, copy number 10–15: DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P.
- chr4:53,377,641–54,446,723, 22 genes, copy number 113: FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1.
- chr12:57,529,633–57,846,729, 30 genes, copy number 94–106 (within-gene range 4–106): DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2.
- chr14:18,333,726–18,412,264, 2 genes, copy number 15–20: CR383658.1, CR383658.2.
- chr14:18,630,318–18,637,421, 3 genes, copy number 9: LINC02297, CR383656.1, CR383656.12.
- chr14:18,889,084–18,909,673, 2 genes, copy number 61: NEK2P1, NF1P7.
- chr16:589,357–1,221,771, 51 genes, copy number 9–12 (within-gene range 6–12): RAB40C, WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2, RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1, METRN, ANTKMT, CCDC78, HAGHL, CIAO3, MSLN, AL031258.1, MSLNL, MIR662, RPUSD1, CHTF18, GNG13, AL023882.1, AL031008.1, LMF1, AL031716.1, AL008727.1, LMF1-AS1, AC009041.3, CEROX1, SOX8, AC009041.1, SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1, AL031598.1, AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6.
- chr18:109,065–122,219, 1 gene, copy number 10 (within-gene range 7–10): ROCK1P1.

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
